Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A18Z, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A18Z-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Multinodular goiter
PROCEDURE: Total thyroidectomy, neck dissection
SPECIFIC CLINICAL QUESTION: Not answered
OUTSIDE TISSUE DIAGNOSIS: Not answered
PRIOR MALIGNANCY: Not answered
CHEMOTHERAPY: Not answered
ORGAN TRANSPLANT: Not answered
IMMUNOSUPPRESSION: Not answered
OTHER DISEASES: Not answered

FINAL DIAGNOSIS:

PART 1: THYROID GLAND, TOTAL THYROIDECTOMY (27 GRAMS) -

- A. THREE FOCI OF PAPILLARY THYROID CARCINOMA, CONVENTIONAL, WITH TALL CELL FEATURES:**
a. 3.6 CM, LEFT LOBE, WITH EXTRATHYROIDAL EXTENSION (see comment).
b. 0.9 CM, RIGHT LOBE, EXTENDING TO MARGIN.
c. 0.2 CM, ISTHMUS.
B. VASCULAR INVASION IS IDENTIFIED.
C. NODULAR THYROID HYPERPLASIA.
D. ONE BENIGN LYMPH NODE ATTACHED TO RIGHT LOBE (0/1).
E. PATHOLOGIC STAGE: pT3 N1b.

PART 2: LYMPH NODES, LEVEL B, NECK DISSECTION -
FOUR BENIGN LYMPH NODES (0/4).

PART 3: RIGHT MODIFIED RADICAL NECK DISSECTION, LEVELS 2A THROUGH 5B -

- A. METASTATIC PAPILLARY THYROID CARCINOMA IN THREE OF THIRTY-TWO LYMPH NODES (3/32).**
B. POSITIVE LYMPH NODES ARE IN LEVELS 2 AND 4.
C. LARGEST METASTATIC FOCUS - 3.2 CM (LEVEL 4).
D. EXTRANODAL SPREAD IS IDENTIFIED.

COMMENT:

Molecular testing was previously performed (see addendum for [REDACTED]) - carcinoma is positive for BRAF p.V600E mutation.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Right Lobe, Left Lobe, Isthmus
TUMOR FOCALITY: Multifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 3.6 cm
Additional Dimensions: 2.7 x 2.4 cm
HISTOLOGIC TYPE:** Papillary carcinoma
PRIMARY TUMOR (pT): pT3
REGIONAL LYMPH NODES (pN): pN1b

Number of regional lymph nodes examined: 37
Number of regional lymph nodes involved: 3

EXTRANODAL EXTENSION: Present
DISTANT METASTASIS (pM): Not applicable
EXTRATHYROIDAL EXTENSION: Present

MARGINS: Extent: Minimal
LYMPH-VASCULAR INVASION: Margin(s) involved by carcinoma
Present

Reviewer Initials	Reviewed: 11/2/11	

Source: NCI Genomic Data Commons file 49123918-a5d6-44ec-92e6-feadb2ab3791 (TCGA-BJ-A18Z.AE63E7FD-7E20-493C-B405-8D18C3DFBEA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).